TCGA case TCGA-WC-A87T — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3eb7aded-8887-4c27-a464-1b50ec090133

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Spindle cell melanoma, type B (the primary disease): ICD-O-3 morphology code: 8774/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,409 days); Year of diagnosis: 2007; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIB; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,600 days (7.1 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 11.
   Pathology details: Additional pathology findings: Other Complex Extravascular Matrix Patterns; Consistent pathology review: Yes; Epithelioid cell percent range: 0%; Extrascleral extension present: No; Measurement type: Pathologic; Spindle cell percent range: >90%; Tumor depth measurement: 10; Tumor shape: Mushroom.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 69.6 years (25,429 days); Days to diagnosis: 2,020 days (5.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 2,020 days (5.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 2,149 days (5.9 years); Disease response: Tumor Free.
- Days to follow up: 2,600 days (7.1 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92.6 kg; Height: 187 cm; BMI: 26.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WC-A87T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-WC-A87T-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WC-A87T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WC-A87T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: 0%.
- Primary pathology, Gene expression profile list: Gene expression profile: Class 1b.
- Primary pathology: Extravascular matrix patterns: Other Complex Patterns; Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Pathologic Measurement.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Skin; New tumor event histology: Squamous Cell Cacinoma; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,600 days; disease-specific survival: no event (censored), 2,600 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,020 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WC-A87T-01A-11D-A39V-01): tumor purity 0.87, ploidy 1.99, whole-genome doublings 0.
